Surgical pathology report (de-identified scan), TCGA case TCGA-HE-A5NF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-A5NF-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Renal cell ca, papillary type.
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Left kidney
Tumour Size (cm)	3
Histology	Renal cell ca, papillary type.
Grade/Differentiation	X
Pathological T	T1a
Pathological N	NX
Clinical M	M0
Histology Comments	Fuhrmann grade 3. Also resected in same surgery, prostate, positive for adenocarcinoma with Gleason score 6/10.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-3
Carcinoma, papillary renal cell
826013
Site: Kidney NOS C64.9
JW 2/11/13

Criteria	JW 2/7/13	Yes	No
Prior Malignancy History	OME adeno-		
Qual/Synchronous Primary Noted	Prostate		

Source: NCI Genomic Data Commons file 6dbe0752-9443-4f7f-a27e-21f165b7f9ce (TCGA-HE-A5NF.D261AB44-5C3E-4107-90BF-9F43C99F57F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).